Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A4FM, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A4FM-01A (Primary Tumor).

[page 1 of 3]
LABORATORY MEDICINE PROG.

Surgical Pathology Consultation Report

Patient Name:	[REDACTED]	Accession #:	[REDACTED]
MRN:	[REDACTED]	Collected:	[REDACTED]
DOB:	[REDACTED]	Received:	[REDACTED]
Gender:	[REDACTED]	Reported:	[REDACTED]
HCN:	[REDACTED]		
Ordering MD:	[REDACTED]		
Copy To:	[REDACTED]		

Specimen(s) Received

1. Nck: Rt neck contents, double tie-superior, single tie-posterior/Fresh tumor banking
2. Lymph node: Rt para-tracheal nodes
3. Thyroid: Total thyroid, stitch marks upper pole, left lobe fresh tumour banking

Diagnosis

1. Metastatic papillary thyroid carcinoma: Lymph nodes, 6 of 31 (right neck) dissection specimen
2. Metastatic papillary thyroid carcinoma: Lymph nodes, 3 (right paratracheal) excisional biopsy
3. Widely invasive bilateral papillary carcinoma, dominant mixed classical and follicular variant with focal tall cell change, 3.0 cm, right, exhibiting extrathyroidal extension and involving surgical margins; underlying mild follicular nodular disease, focal thyroiditis and ectopic serous-mucinous glands, right: Thyroid
Infiltrating papillary thyroid carcinoma: Parathyroid, right perithyroidal
Slightly cellular gland: Parathyroids, 2, right and left intrathyroidal
No pathological diagnosis: Thymus, isthmic
Metastatic papillary thyroid carcinoma: Lymph node, 1, right perithyroidal
Metastatic papillary thyroid carcinoma: Lymph nodes, 2, isthmic
No pathological diagnosis: Lymph nodes, 3, left perithyroidal
- Total thyroidectomy specimen. See Comment.
- ICD-0-3*
Carcinoma, papillary, thyroid 8260/3
Site: thyroid, NOS C73.9
hw
10/2/12

Comment

Since the surgical margins are involved by tumor, evaluation of the extent of extrathyroidal extension cannot be reliably performed on this specimen. Therefore, intraoperative findings may alter the stage of the primary tumor.

Synoptic Data

Procedure:	Total thyroidectomy with right neck dissection
Received:	In formalin
Specimen Integrity:	Intact
Specimen Size:	Right lobe:
	5.0 cm
	2.9 cm
	2.2 cm
	Left lobe:
	4.2 cm
	2.5 cm

[page 2 of 3]
Surgical Pathology Consultation Report

1.1 cm
Isthmus +/- pyramidal lobe:
3.2 cm
1.1 cm
0.5 cm
Right neck dissection:
12.5 cm
4.5 cm
1.4 cm
Specimen Weight: 28 g
Tumor Focality: Multifocal, bilateral

DOMINANT TUMOR
Tumor Laterality: Right lobe
Tumor Size: Greatest dimension: 3.0 cm
Additional dimension: 2.5 cm
Additional dimension: 2.1 cm
Histologic Type: Papillary carcinoma, classical (usual)
Papillary carcinoma, follicular variant
Papillary carcinoma, other variant: with focal tall cell change (10%)
Classical (papillary) architecture
Follicular architecture
Classical cytomorphology
Tall cell cytomorphology
Histologic Grade: Not applicable
Margins: Margin(s) involved by carcinoma
Tumor Capsule: Partially encapsulated
Tumor Capsular Invasion: Present, extent widely invasive
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Present
Extrathyroidal Extension: Present, minimal

SECOND TUMOR
Tumor Laterality: Left lobe
Tumor Size: Greatest dimension: 1.6 cm
Additional dimensions: 1.1 cm
Histologic Type: Papillary carcinoma, classical (usual)
Papillary carcinoma, follicular variant
Classical (papillary) architecture
Follicular architecture
Classical cytomorphology
Histologic Grade: Not applicable
Margins: Margins uninvolved by carcinoma
Distance of invasive carcinoma to closest margin: 0.1 mm
Tumor Capsule: Partially encapsulated
Tumor Capsular Invasion: Present, extent widely invasive
Lymph-Vascular Invasion: Not identified
Perineural Invasion: Not identified
Extrathyroidal Extension: Not identified
TNM Descriptors: m (multiple primary tumors)
Primary Tumor (pT): pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension
(eg, extension to sternothyroid muscle or perithyroid soft tissues)
Regional Lymph Nodes (pN): pN1b: Metastases to unilateral, bilateral or contralateral cervical or superior
mediastinal lymph nodes
Number of regional lymph nodes examined: 40
Number of regional lymph nodes involved: 12
Lymph Node, Extranodal Extension Not identified
Distant Metastasis (pM): Not applicable
Additional Pathologic Findings: Adenomatoid nodule(s) or Nodular follicular disease
Thyroiditis, focal (nonspecific)

[page 3 of 3]
Surgical Pathology Consultation Report

Parathyroid gland(s), other: infiltrating papillary carcinoma (right); Mild cellular gland (right and left intrathyroidal)
Other: ectopic serous and mucinous glands, right lobe

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Gross Description

1. The specimen labeled with the patient's name and as "right neck contents" consists of a piece of oriented fibroadipose tissue that measures 12.5 cm SI x 4.5 cm AP x 1.4 cm ML and contains multiple lymph nodes that range from 0.5 cm to 2.5 cm in maximum dimension.

Superior third portion of the specimen:

- 1A three lymph nodes bisected
- 1B one lymph node bisected
- 1C multiple lymph nodes
- 1D multiple lymph nodes
- 1E multiple lymph nodes

Mid third portion of the specimen

- 1F two lymph nodes
- 1G one lymph node bisected
- 1H multiple lymph nodes

Inferior third portion of specimen

- 1I one lymph node bisected
- 1J one lymph node bisected
- 1K multiple lymph nodes
- 1L two lymph nodes

2. The specimen labeled with the patient's name and as "right paratracheal nodes" consists of 3 gray-brown nodules that measure from 0.6 x 0.4 x 0.4 cm to 1.7 x 1.2 x 0.7 cm received in 10% buffered formalin. The specimen is submitted in toto as follows:

- 2A two lymph nodes
- 2B one lymph node bisected.

3. The specimen labeled with the patient's name and as "total thyroid, stitch marks upper pole, left lobe fresh tumor banking" consists of an oriented thyroid gland that weighs 28.0 g. The right lobe measures 5.0 cm SI x 2.9 cm ML x 2.2 cm AP, the left lobe measures 4.2 cm SI x 2.5 cm ML x 1.1 cm AP and the isthmus measures 3.2 cm SI x 1.1 cm ML x 0.5 cm AP. The external surfaces have fibrous adhesions and are painted with silver nitrate. No parathyroid glands or no lymph nodes are identified grossly. The upper to lower right lobe contains a well delineated partly calcified nodule that measures 3.0 cm SI x 2.5 cm ML x 2.1 cm AP. The upper mid to lower left lobe contains a well delineated nodule that measures 1.6 cm SI x 1.1 cm ML x 0.8 cm AP. The remainder of the thyroid tissue is unremarkable. Sections of right lobe nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

- 3A-J right lobe, superior to inferior
- 3K-L isthmus
- 3M-Q left lobe, superior to inferior

Microscopic Description

One of the metastatic nodes exhibits focal tall cell change.

Reviewed Initials:	9/10/21/12	

Source: NCI Genomic Data Commons file ca5baae6-d099-4169-8e9f-f79b73afc694 (TCGA-EM-A4FM.262BB6C6-7DFB-40E4-8C69-65F986CF74BB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).